Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1J9, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1J9-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

page 1 / 2
Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 3/11/11 *lw*

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender: F

Material: **Multiple organ resection – left breast with axillary tissues**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**Clinical diagnosis: **Cancer of the left breast.**

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in 10-75% of neoplastic cell nuclei.

No progesterone receptors found in neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Positive reaction in invasive cancerous cells (Score = 3+)

Compliance validated by:

Examination performed on

Macroscopic description:

Left breast sized 18 x 12.5 x 2.5 cm removed along with axillary tissues sized 9 x 5 x 1 cm and a 14 x 4 cm skin flap. Weight 350 g. Tumour sized 1.8 x 1.5 x 1.9 cm on the boundary of outer quadrants, 2.0 cm from the lower boundary, 0.3 cm from the base and 0.7 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG2 (2 + 3 +1:4 mitoses/10 HPF, visual area diameter 0.55 mm).

Mamilla sine laesionibus.

Lesions of the type mastopathia fibrosa et cystic, calcificationes.

Invasive lesions situated 7 cm from the base.

Axillary lymph nodes:

Lymphonodulitis chronica et sinus histiocytosis (No. VI).

HPVAA Discrepancy		X

[page 2 of 2]
Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistrae. Invasive ductal carcinoma of the left breast.

(NHG2, pT1c, pN0).

Compliance validated by:

CALL YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 7eb719e2-d7f6-40b7-bc93-f79900dd1af1 (TCGA-D8-A1J9.D80E9389-AAD8-4EEB-9DE0-5DE57B5E5F6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).